Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A20Q, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A20Q-01A (Primary Tumor).

ICD-0-3

Carcinoma, urothelial 8120/3

Site: bladder, trigone C67.0

hw 4/7/11

PATIENT HISTORY:

Clinical history is not given.

PRE-OP DIAGNOSIS: Bladder cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Cystoprostatectomy / neobladder construction.

ADDENDA:

Addendum

Collection Date:

Multiple additional deeper levels were evaluated from the right distal ureteral margin (part 4). These deeper sections show fibrovascular, neural and adipose tissue. No lining urothelial is seen. No evidence of urothelial carcinoma nor urothelial carcinoma in situ (CIS) are seen.

This completes my current evaluation of this case. The diagnoses rendered earlier remain unchanged. Thank you for involving us in the care of this patient.

FINAL DIAGNOSIS:

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION -

- A. METASTATIC CARCINOMA IN ONE OF ELEVEN LYMPH NODES (1/11).
- B. NO EXTRACAPSULAR EXTENSION PRESENT.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -

- A. METASTATIC CARCINOMA IN THREE OF TWELVE LYMPH NODES (3/12).
- B. EXTRACAPSULAR EXTENSION PRESENT.

PART 3:

BLADDER, PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL CYSTOPROSTATECTOMY -

- A. INVASIVE UROTHELIAL CARCINOMA (3.3 CM), HIGH GRADE (WHO/ISUP), GRADE 3 OF 4 (ASH).
- B. THE CARCINOMA EXTENDS INTO THE PERIVESICAL ADIPOSE TISSUE.
- C. THE INKED PERIVESICAL SOFT TISSUE SURGICAL MARGIN IS INVOLVED VERY FOCALLY IN THE LEFT TRIGONE/ LEFT LATERAL WALL REGION OF THE BLADDER (SLIDE 3C).
- D. METASTATIC ADENOCARCINOMA IN ONE OF ONE LEFT PERIVESICAL LYMPH NODES (1/1).
- E. NO CARCINOMA IN SITU (CIS) IDENTIFIED.
- F. ANGIOLYMPHATIC INVASION IDENTIFIED.
- G. TNM PATHOLOGIC STAGING = T3bN2MX.
- H. TNM HISTOPATHOLOGIC GRADE = G3.
- I. BENIGN PROSTATIC TISSUE WITH FOCAL CHRONIC INFLAMMATION.

PART 4:

URETER, RIGHT DISTAL, BIOPSY -

- A. BENIGN FIBROADIPOSE TISSUE.
- B. NO TUMOR PRESENT.

MICROSCOPIC:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE: Radical cystoprostatectomy
TUMOR SITE: Trigone, Left lateral wall
TUMOR SIZE: Greatest dimension: 3.3 cm
HISTOLOGIC TYPE: Urothelial (transitional cell) carcinoma
ASSOCIATED EPITHELIAL LESIONS: None identified
HISTOLOGIC GRADE: Urothelial carcinoma - High-grade
TUMOR CONFIGURATION: Solid/nodule, Ulcerated
PATHOLOGIC STAGING (pTNM): pT3b
pN2

Number of nodes examined: 23
Number of nodes involved: 4

pMX

MARGINS:

Margin(s) involved by invasive carcinoma
Margin(s): left ureteral

VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L): Present

DIRECT EXTENSION OF INVASIVE TUMOR: Perivesical fat

ADDITIONAL PATHOLOGIC FINDINGS: Inflammation/regenerative changes

Case is (crr):	7/11/11	DISQUALIFIED

Source: NCI Genomic Data Commons file 3f002827-473f-4bc3-a63c-0d1a76a10b34 (TCGA-BT-A20Q.E686B42F-3A8C-4181-836E-79D4443DC0CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).